Somatic mutation profile of tumor specimen TCGA-AF-2690-01A (aliquot TCGA-AF-2690-01A-02D-1733-10) from TCGA case TCGA-AF-2690, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 77.0 years (28,119 days).
Specimen TCGA-AF-2690-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62c5106f-14e7-4258-9dc9-efe765529fb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-2690-10A (Blood Derived Normal), aliquot TCGA-AF-2690-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbbd1b6c-d511-49f4-b2ba-d1a59defe7ca

The open-access MAF lists 88 somatic variants for this specimen: 60 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 25, Nonsense Mutation 6, 3'UTR 2, Splice Region 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684436, COSV61688043; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 38/88 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM9 | c.2073G>C p.M691I | Missense Mutation (SNP) | VAF 222/404 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65959066; called by muse, varscan2
- ADAM9 | c.2186G>T p.R729I | Missense Mutation (SNP) | VAF 174/328 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV65962969; called by muse, mutect2, varscan2
- ADAMTS10 | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1464708065, COSV99546764; called by muse, mutect2
- ANKS1A | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV64465186; called by muse, mutect2, varscan2
- ANP32D | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs750180206, COSV56980480, COSV99874337; called by muse, mutect2, varscan2
- AP002512.3 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.178); catalogued as rs367845258; called by muse, mutect2, varscan2
- APC | c.4245del p.S1415Rfs*4 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as COSV57334974; called by mutect2, pindel, varscan2
- CDH22 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.532); catalogued as rs972504580, COSV64839972; called by muse, mutect2, varscan2
- CENPF | c.6040G>A p.E2014K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV100871666; called by muse, mutect2, varscan2
- CHORDC1 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV57707159; called by muse, mutect2, varscan2
- CRB1 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937362854, COSV66328905; called by muse, mutect2, varscan2
- CWC15 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as COSV99688499; called by muse, mutect2, varscan2
- DEGS1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV60380341; called by muse, mutect2, varscan2
- DNMBP | c.3010G>T p.V1004F | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60634379; called by muse, mutect2, varscan2
- EPN1 | c.1703C>G p.A568G (on ENST00000270460 / NM_001321263.1; = p.A542G on NM_013333.3) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV50046705; called by muse, mutect2, varscan2
- FOXP3 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as CM0911379, COSV66052168; called by muse, mutect2, varscan2
- GALNS | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as rs780393705, COSV99243138; called by muse, mutect2, varscan2
- GPR55 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs541186477, COSV101235633, COSV67408967; called by muse, mutect2, varscan2
- ITIH1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.915); catalogued as rs1197545618, COSV56256169; called by muse, mutect2, varscan2
- KCNT1 | c.2282G>A p.R761Q (on ENST00000488444; = p.R780Q on NM_020822.3) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as rs780759196, COSV53697768; called by muse, mutect2, varscan2
- KIAA1549L | c.4699G>A p.A1567T (on ENST00000321505; = p.A1864T on NM_012194.3) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as rs749282621, COSV58592349; called by muse, mutect2, varscan2
- KRT6A | c.1471T>C p.S491P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58108248; called by muse, mutect2, varscan2
- LARGE1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV61673899; called by muse, mutect2, varscan2
- LRP1B | c.4313G>T p.R1438M | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV67283666; called by muse, mutect2, varscan2
- MYH7B | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771512439, COSV52685284; called by muse, mutect2, varscan2
- NFKB1 | c.563T>G p.L188R (on ENST00000394820 / NM_001382627.1; = p.L189R on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV56961681; called by muse, mutect2, varscan2
- NLRP5 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs780213439, COSV66764769; called by muse, mutect2, varscan2
- NT5C1B | c.1200C>T p.Y400= (on ENST00000359846 / NM_001199086.2; = p.Y340= on NM_033253.4) | Splice Region (SNP) | VAF 19/87 reads (22%) | catalogued as rs148193506; called by muse, mutect2, varscan2
- OBSL1 | c.3940C>T p.R1314W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298506284, COSV54710538; called by muse, mutect2, varscan2
- PAM | c.2749G>A p.G917R (on ENST00000438793 / NM_001319943.1; = p.G918R on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.747); catalogued as COSV99173375; called by muse, mutect2, varscan2
- PAPOLB | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV68201845; called by muse, mutect2, varscan2
- PAWR | c.920T>C p.I307T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100174218; called by muse, mutect2, varscan2
- PKP2 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs543281875, COSV50726677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG4B | c.1361G>A p.R454H (on ENST00000283426; = p.R810H on NM_052909.5) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.743); catalogued as rs368262746, COSV52048591; called by muse, mutect2, varscan2
- POLR1B | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54504532; called by muse, mutect2, varscan2
- PPP1R16B | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1270812580, COSV55386193; called by muse, mutect2
- RAD54L2 | c.3376A>G p.K1126E | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV56582153; called by muse, mutect2, varscan2
- RGMA | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.961); catalogued as rs763103195, COSV61237379; called by muse, mutect2, varscan2
- SCN7A | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV69275302; called by muse, mutect2, varscan2
- SDC2 | c.479C>A p.A160E | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56232841; called by muse, mutect2, varscan2
- SLC26A8 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as rs867629953, COSV62885400; called by muse, mutect2
- SLC2A10 | c.1367G>A p.W456* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | catalogued as COSV100826363, COSV63715464; called by muse, mutect2
- SORCS3 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs142652556; called by muse, mutect2, varscan2
- SPTAN1 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as rs368406599; ClinVar: likely benign; called by muse, mutect2
- STARD8 | c.3066G>T p.K1022N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99366751; called by muse, mutect2, varscan2
- SYDE1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs866999751, COSV61442681, COSV61443036; called by muse, mutect2, varscan2
- TFF2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs1204626263, COSV52295893; called by muse, mutect2, varscan2
- TNR | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs774052903, COSV54873532; called by muse, mutect2, varscan2
- TSGA10IP | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs548379525, COSV56713306; called by muse, varscan2
- VSTM2A | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs144355001; called by muse, mutect2, varscan2
- WBP2NL | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV60920505; called by muse, mutect2, varscan2
- WDR88 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV63453098; called by muse, mutect2, varscan2
- YTHDF3 | c.1433A>C p.E478A | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101572379; called by muse, mutect2, varscan2
- ZNF212 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60026418; called by muse, mutect2, varscan2
- CDK8 | c.315+2dup p.X105_splice | Splice Site (INS) | VAF 40/129 reads (31%) | called by mutect2, pindel, varscan2
- NOB1 | c.1001dup p.Y334* | Nonsense Mutation (INS) | VAF 7/62 reads (11%) | called by mutect2, pindel
- SPEF2 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADCY8 | c.1716G>A p.E572= | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as COSV53932088; called by muse, mutect2, varscan2
- ATF4 | c.286T>C p.L96= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV57478082; called by muse, mutect2, varscan2
- CPOX | c.348G>A p.P116= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV51640330; called by muse, mutect2, varscan2
- EPPK1 | c.1611C>T p.S537= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs550921737, COSV101599823; called by muse, mutect2, varscan2
- ERLIN2 | c.10T>C p.L4= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs1339184582, COSV99379626; called by muse, mutect2, varscan2
- FGD5 | c.1350G>A p.S450= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs753667680, COSV53254393; called by muse, mutect2, varscan2
- FUT2 | c.423G>A p.P141= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs150802597, COSV101218033; called by muse, mutect2, varscan2
- GBF1 | c.1383C>T p.H461= (on ENST00000369983 / NM_001377137.1; = p.H460= on NM_004193.3) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100890464; called by muse, mutect2, varscan2
- GRIP2 | c.816G>A p.P272= (on ENST00000619221; = p.P175= on NM_001080423.4) | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs368903779; called by muse, mutect2, varscan2
- GXYLT2 | c.732C>T p.H244= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs372388479; called by muse, mutect2, varscan2
- IRF3 | c.729C>T p.V243= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV99881062; called by muse, mutect2, varscan2
- KCNA3 | c.457C>A p.R153= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV100871256, COSV63902686; called by muse, mutect2, varscan2
- KCNC2 | c.873G>A p.V291= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV54382087; called by muse, mutect2, varscan2
- MUC13 | c.1236A>C p.G412= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV60701589; called by muse, mutect2, varscan2
- NBEAL2 | c.5886C>T p.I1962= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs765396438, COSV52760112; called by muse, mutect2, varscan2
- NYAP2 | c.1053C>T p.D351= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV99796465; called by muse, mutect2
- OBSCN | c.16032G>A p.S5344= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs951737840, COSV99477054; called by muse, mutect2, varscan2
- PARD6A | c.258G>A p.P86= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1379234407, COSV54670949; called by muse, mutect2, varscan2
- PCDHA1 | c.735C>T p.A245= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV65377418; called by muse, mutect2, varscan2
- POU3F4 | c.552C>T p.S184= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV64541541; called by muse, mutect2, varscan2
- TSHR | c.261G>A p.V87= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1383192232, COSV53334041; called by muse, mutect2, varscan2
- TTN | c.82657A>C p.R27553= (on ENST00000591111; = p.R20129= on NM_003319.4) | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as COSV60402921; called by muse, mutect2, varscan2
- USF2 | c.723C>T p.N241= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs578120409, COSV55887552; called by muse, mutect2, varscan2
- USP42 | c.1656C>T p.P552= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs367952373, COSV60365103; called by muse, mutect2, varscan2
- WDR59 | c.1176G>A p.Q392= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as rs773071843, COSV50946799; called by muse, mutect2, varscan2
- ATAD3B | c.*453C>T | 3'UTR (SNP) | VAF 31/79 reads (39%) | catalogued as rs112543187; called by muse, mutect2, varscan2
- MIR517C | n.60G>A | RNA (SNP) | VAF 17/113 reads (15%) | catalogued as rs764618172; called by muse, mutect2, varscan2
- ZNF99 | c.*561C>A | 3'UTR (SNP) | VAF 6/21 reads (29%) | catalogued as COSV68057286, COSV68057378; called by muse, varscan2
